Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4329, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4329-01A (Primary Tumor).

[page 1 of 2]
Other Related Data:

Billing Type:

Financial Number:

Clinical Diagnosis & History:

5 x 7 cm heterogenous lower pole mass.

Specimens Submitted:

1: SP: Right kidney

2: SP: Right para-caval lymph nodes

DIAGNOSIS:

- 1) KIDNEY, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE II/IV. THE PATTERN OF GROWTH IS ACINAR. THE TUMOR GREATEST DIAMETER IS 7.5 CM. THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA. INVASION OF THE RENAL VEIN IS PRESENT. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY SHOWS PATCHY CHRONIC INFLAMMATION.
- 2) LYMPH NODE, RIGHT PARA-CAVAL; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).

Gross Description:

1) The specimen is received fresh, labeled "Right kidney". It consists of a kidney, portion of ureter, portion of renal blood vessels and perinephric adipose tissue weighing 580 grams overall. The kidney measures 12.5 x 6.5 x 5.5 cm. The portion of ureter measures 7 cm in length and 0.3 cm in diameter. The kidney is bivalved to reveal an ill-defined tumor involving the lower half of the kidney and measuring 7.5 x 5 x 3.5 cm. The tumor is composed of gray-yellow focally necrotic tissue. The Gerota's fascia is inked. The tumor is serially sectioned to

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

reveal that it abuts the renal capsule, however, it does not extend into the perinephric adipose tissue. The collecting system is free of tumor. The urothelium of the renal pelvis and ureter is tan and smooth. The tumor involves the adipose tissue close to renal pelvis, and is present within the lumen of the renal vein. The renal vein surgical margin is free of tumor. The rest of the renal parenchyma is unremarkable. No adrenal gland is identified. Representative sections are submitted. Fresh tumor is saved for TPS and EM. Gross photographs are taken.

Summary of Sections:

SM - surgical margins of the ureter and renal blood vessels
TG - tumor in relation Gerota's fascia
TC - tumor in relation to renal capsule
TF - tumor within the pelvic fat
TCS - tumor and collecting system
TK - tumor and normal kidney
RV - renal vein
K - normal kidney

2) The specimen is received in formalin, labeled, "Right paracaval lymph node". It consists of a single piece of adipose tissue measuring 5.0 x 1.0 x 0.2 cm. Embedded within the adipose tissue is a possible lymph node which measures 4.0 cm in greatest dimension. The possible lymph node was cut into pieces and each fragment was further bisected. The node is submitted entirely.

Summary of Sections:

PLN - possible lymph node

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	K		1	1	N
	RV		1	1	
	SM		1	M	
	TC		3	3	
	TCS		1	1	
	TF		2	2	
	TG		4	4	
	TK		1	1	
2	PLN		4	4	Y

Source: NCI Genomic Data Commons file 3f250648-7cf6-4c8a-b439-a006480c7eb3 (TCGA-BP-4329.54F2CE97-760F-4EA7-9FA1-4DCAC28AC8FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).